HCMI case HCM-SANG-0780-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/9ddacfb1-46c5-4b93-8f96-937ef10e08f2

Demographics
Sex at birth: male; Days to birth: -18,810 days (51.5 years before the index date).

Diagnoses (1)
1. Adenocarcinoma, intestinal type: ICD-O-3 morphology code: 8144/3; ICD-10 code: C25.3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Pancreatic duct; Classification of tumor: primary; Tumor grade: G2; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No; Uicc pathologic n: N1; Uicc pathologic stage: Stage IIB; Uicc pathologic t: T3; Uicc staging system edition: 7th.
   Pathology details: Peripancreatic lymph nodes positive: 1-3; Peripancreatic lymph nodes tested: 12.
   Recorded as not given: neoadjuvant treatment (type not reported).

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples)
- Sample HCM-SANG-0780-C25-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
- Sample HCM-SANG-0780-C25-10A-01D-A80T-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Samples HCM-SANG-0780-C25-85A-01D-A80T-32, HCM-SANG-0780-C25-85A-01R-A80W-32 (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
